Somatic mutation profile of tumor specimen 0DHZS4 from CCDI case PBBUNY, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Ependymoma, NOS; Tissue or organ of origin: Occipital lobe; Age at diagnosis: 8.3 years (3,036 days).
Specimen 0DHZS4: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 493d2949-ceb6-4d2e-b449-ecb658887e96.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DHZRU (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ce5c8d35-c92c-4d6b-917b-eb71471b3fb0

The open-access MAF lists 12 somatic variants for this specimen: 9 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, Silent 2, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACTL9 | c.991C>T p.R331C | Missense Mutation (SNP) | VAF 85/848 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.111); catalogued as COSV100185290, COSV61007537; called by muse, mutect2, varscan2
- AGAP2 | c.2426C>T p.T809M (on ENST00000547588 / NM_001122772.2; = p.T473M on NM_014770.4) | Missense Mutation (SNP) | VAF 70/820 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.967); catalogued as rs747768095; called by muse, mutect2
- BIN2 | c.1030G>A p.A344T | Missense Mutation (SNP) | VAF 66/710 reads (9%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.001); catalogued as rs150210505, COSV57205346; called by muse, mutect2
- OR4S1 | c.482C>T p.T161M | Missense Mutation (SNP) | VAF 78/482 reads (16%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.611); catalogued as rs371001252, COSV100180378; called by muse, mutect2, varscan2
- OR5M3 | c.679C>T p.R227C | Missense Mutation (SNP) | VAF 449/1219 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.009); catalogued as rs769332657, COSV56566646; called by muse, mutect2, varscan2
- ZNF541 | c.1876C>T p.R626C | Missense Mutation (SNP) | VAF 133/340 reads (39%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.809); catalogued as COSV54543763; called by muse, mutect2, varscan2
- CHD6 | c.1124T>C p.V375A | Missense Mutation (SNP) | VAF 324/1640 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.626); called by muse, mutect2, varscan2
- HCN3 | c.1714C>G p.Q572E | Missense Mutation (SNP) | VAF 32/1320 reads (2%) | SIFT deleterious (0.04); PolyPhen benign (0.358); called by muse, mutect2
- WDR90 | c.4706C>T p.A1569V | Missense Mutation (SNP) | VAF 22/682 reads (3%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.472); called by muse, mutect2
- AP2A1 | c.234G>A p.E78= | Silent (SNP) | VAF 52/1416 reads (4%) | called by muse, mutect2
- MYO6 | c.3063C>T p.A1021= | Silent (SNP) | VAF 123/1507 reads (8%) | catalogued as rs369384374; called by muse, mutect2
- FAM204A | c.353+20G>A | Intron (SNP) | VAF 40/596 reads (7%) | called by muse, mutect2
